Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7YD, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7YD-01A (Primary Tumor).

Patient: [REDACTED]

Surgical Pathology: Final [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

Not provided.

GROSS EXAMINATION:

A. "Brain tumor (AF1, AF2)", received fresh for frozen section. A 1.0 x 0.8 x 0.4 cm aggregate of soft white-tan tissue was entirely received for frozen sectioning. A fragment of the tissue was submitted as frozen sectioning AF1 and the frozen section remnant is submitted in toto in a mesh bag in block A1. Two more tissue fragments were submitted for frozen sectioning AF2 and the frozen section remnant are submitted in toto in a mesh bag in block A2. The remainder of the tissue is submitted in toto in a mesh bag in block A3.

B. "Brain tumor (BF1)", received fresh for frozen sectioning. A 1.5 x 1.0 x 0.3 cm aggregate of soft white-tan tissue was received for frozen sectioning. A fragment of the tissue was submitted for frozen sectioning in BF1 and the frozen section remnant is submitted in toto in a mesh bag in block B1. The remainder of the tissue is submitted in toto in a mesh bag in block B2.

C. "Brain tumor", received fresh and placed in formalin. An 11.5 x 7.5 x 1.0 cm aggregate of soft yellow-tan tissue with a 1.3 x 1.0 x 0.5 cm dark and light red soft lesion is received. Representative sections are submitted in blocks C1-8.

INTRA OPERATIVE CONSULTATION:

- A. "Brain tumor": AF1-AF2 - hypercellular brain
- B. "Brain tumor ?" BF1- glioma

MICROSCOPIC EXAMINATION:

Specimen in container A labeled "brain tumor AF1, AF2", in container B labeled "brain tumor BF1", and in container C labeled "brain tumor" consists of brain tissue which is infiltrated and replaced by a population of anaplastic astrocytes. The cells are very pleomorphic and tumor giant cells are seen in many areas. Mitotic figures including abnormal mitoses are present. Endothelial proliferation is focally seen but necrosis is not identified.

DIAGNOSIS:

- A. "BRAIN TUMOR AF1, AF2":

ANAPLASTIC ASTROCYTOMA.

- B. "BRAIN TUMOR BF1":

ANAPLASTIC ASTROCYTOMA.

- C. "BRAIN TUMOR":

ANAPLASTIC ASTROCYTOMA.

ICD-O-3
Astrocytoma, grade III 9481/3
Site: Brain, supratentorial NOS (71.0)
Brain NOS (71.9)
7/5/14

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

Source: NCI Genomic Data Commons file c9aed39f-9269-45f1-8b96-f1ef52f19351 (TCGA-E1-A7YD.B371FF08-C874-4A6E-9CF9-C1931F28ADED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).